Surgical pathology report (de-identified scan), TCGA case TCGA-24-1426, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1426-01A (Primary Tumor).

[page 1 of 3]
Patient Name:
DOB:

Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT FINAL

TCGA-24-1426

Patient Name:

Address:

Gender:

DOB:

Service:

Location:

MRN:

Hospital #:

Patient Type:

Accession #

Taken:

Received:

Accessioned:

Reported:

Physician(s):

DIAGNOSIS:

OVARIES, LEFT, PROCEDURE NOT STATED (INCLUDING FS1)

- HIGH GRADE SEROUS CARCINOMA WITH EXTENSIVE SURFACE INVOLVEMENT
- SEE SYNOPSIS

FALLOPIAN TUBE, LEFT, PROCEDURE NOT STATED

- HIGH GRADE SEROUS CARCINOMA INVOLVING FALLOPIAN TUBE LUMEN

OVARIES, RIGHT, PROCEDURE NOT STATED (INCLUDING FS1)

- HIGH GRADE SEROUS CARCINOMA WITH EXTENSIVE SURFACE INVOLVEMENT

FALLOPIAN TUBES, BILATERAL, PROCEDURE NOT STATED

- HIGH GRADE SEROUS CARCINOMA INVOLVING FIMBRIA, LYMPHOVASCULAR SPACES AND FALLOPIAN TUBE LUMEN

UTERUS AND CERVIX, PROCEDURE NOT STATED

- HIGH GRADE SEROUS CARCINOMA INVOLVING UTERINE SEROSA AND OUTER MYOMETRIUM
- ADENOMYOSIS WITH TUBAL METAPLASIA AND STROMAL CALCIFICATION
- PROLIFERATIVE ENDOMETRIUM
- LEIOMYOMA
- CERVIX WITH MILD CHRONIC INFLAMMATION

LARGE INTESTINE, "RECTAL TUMOR," BIOPSY

- HIGH GRADE SEROUS CARCINOMA

SOFT TISSUE, FALCIFORM LIGAMENT, BIOPSY

- HIGH GRADE SEROUS CARCINOMA

SOFT TISSUE, GASTRIC FOLIC OMENTUM, BIOPSY

- HIGH GRADE SEROUS CARCINOMA

SOFT TISSUE, LESSER CURVATURE OF STOMACH, BIOPSY

- HIGH GRADE SEROUS CARCINOMA

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

[page 2 of 3]
Patient Name:
DOB:

Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT

luteum left along with a single cystic space that measures 1.6 cm in greatest dimension. Labeled B1, B2 - anterior and posterior cervix; B3, B4 - anterior and posterior endocervical canal; B5 to B8 - anterior and posterior endomyometrium; B9 to B12 - tumor; B13 - fallopian tube. Labeled B14 - B24 additional sections. Jar 3.

The third container is labeled "rectal tumor." It consists of multiple fragments of tan-brown and brown-black soft tissue that measure ~3 x 3 x 0.5 cm in aggregate. Labeled C1. Jar 1.

The fourth container is labeled "lacriform ligament." It contains two fragments of tan-yellow and tan-white fibroadipose tissue that measure 11 x 6 x 3 cm in aggregate. The surface of the fibroadipose tissue is covered with multiple, small, tan-white nodules that appear granular, consistent with the above described ovarian tumors. The greatest collection measures 3 cm in greatest dimension. Labeled D1 - representative sections of tumor deposits. Jar 1.

The fifth container is labeled "gastric folic omentum." It contains a single piece of omentum that measures 57 x 18 x 3 cm in greatest dimension. The entire omentum is involved by metastatic tumor (omental caking). Labeled E1. Jar 4.

The sixth container is labeled "lesser curvature of stomach." It contains multiple pieces of fibroadipose tissue that also appear to be involved by tumor, and measure 6 x 5 x 2.5 cm in aggregate. Labeled F1. Jar 1.

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

HISTOPATHOLOGIC TYPE

The histologic diagnosis is high grade serous carcinoma

TUMOR LOCATION

The locations of the primary tumor(s) are the right and left ovary

HISTOLOGIC GRADE

The histologic grade is poorly differentiated (G3)

TUMOR INVASION

Tumor is identified on the ovarian surface(s)

Tumor does invade the adjacent fallopian tube/peritubal soft tissue

TUMOR INVOLVEMENT

Tumor involvement of the pelvic peritoneum/soft tissue is present

Tumor involvement of the extrapelvic peritoneum is present

Tumor involvement of the omentum is present

TUMOR SIZE

The maximum dimension of tumor implants outside the true pelvis is greater than or equal to 2 cm

PRIMARY TUMOR (T)

Based on the above information, the primary tumor is classified as macroscopic peritoneal metastasis beyond pelvis more than 2 cm in greatest dimension or regional lymph node metastasis (T3c/IIIC)

REGIONAL LYMPH NODES (N)

The regional lymph nodes cannot be assessed (NX)

DISTANT METASTASIS (M)

The status of distant tumor site is not known (MX)

STAGE GROUPING

The Final AJCC/UICC/FIGO stage is T3c,Nx,Mx (Stage IIIC)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

[page 3 of 3]
Patient Name
DOE

Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT

Source: NCI Genomic Data Commons file 396962a4-dac0-4390-87a1-697f9b898d54 (TCGA-24-1426.72914511-B2F7-484F-A7AB-3F4F1868F2CB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).